Gene-level copy-number profile of tumor specimen HTMCP-03-06-02076-01B from CGCI case HTMCP-03-06-02076, project CGCI-HTMCP-CC (HIV+ Tumor Molecular Characterization Project - Cervical Cancer). Sex at birth: female; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, nonkeratinizing, NOS; Tissue or organ of origin: Cervix uteri; FIGO stage: Stage IB2; Tumor grade: G3; Age at diagnosis: 32.8 years (11,983 days).
Specimen HTMCP-03-06-02076-01B: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file a72b5b77-7566-41db-9050-1292ba16ad2e.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator HTMCP-03-06-02076-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,235 have no estimate.
https://portal.gdc.cancer.gov/files/d03b43cc-9e2c-47dd-8c8b-e705b87e5178

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 102; copy number 1: 6,803; copy number 2: 47,776; copy number 3: 3,213; copy number 4: 261; copy number 5: 156; copy number 6: 67; copy number 9: 2; copy number 10: 2; copy number 13: 3; copy number 14: 1; copy number 16: 2.

Homozygous deletions (total copy number 0; autosomes only): 102 genes in 16 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:11,869–31,109, 5 genes: DDX11L1, WASH7P, MIR6859-1, MIR1302-2HG, MIR1302-2.
- chr1:120,354,987–120,355,148, 1 gene: U1.
- chr1:143,419,625–143,500,512, 7 genes: AC239859.5, RNA5SP533, AC239859.3, AC239859.4, NKAIN1P1, AC239859.2, LINC02799.
- chr1:143,874,793–143,905,966, 3 genes (within-gene range 0–2): FCGR1CP, H2BP2, H3-2.
- chr1:223,947,605–223,950,416, 1 gene: CICP5.
- chr2:94,725,674–94,738,249, 3 genes: CNN2P11, GXYLT1P7, CNN2P8.
- chr2:130,036,958–130,129,222, 6 genes (within-gene range 0–2): KLF2P1, CYP4F27P, POTEF, AC018865.1, POTEF-AS1, RNU6-1049P.
- chr3:59,747,277–61,251,459, 8 genes (within-gene range 0–1): FHIT, AC093418.1, AC104164.2, MIR548BB, PPIAP70, AC104164.1, PPIAP71, U3.
- chr4:49,486,926–49,589,529, 12 genes: AC119751.3, ANKRD20A17P, AC119751.5, AC119751.2, AC119751.8, AC119751.7, MTCO3P42, AC119751.1, AC119751.6, SNX18P24, AC119751.4, SNX18P25.
- chr7:146,208,665–146,208,819, 1 gene (within-gene range 0–2): AC073418.1.
- chr9:64,439,346–64,440,180, 1 gene: SNX18P9.
- chr9:67,832,765–67,920,552, 2 genes (within-gene range 0–14): ANKRD20A1, RNU6-368P.
- chr9:68,232,003–68,330,626, 5 genes (within-gene range 0–2): CBWD3, AL353608.4, FOXD4L3, AL353608.3, AL353608.1.
- chr11:60,699,585–60,744,212, 2 genes: MS4A8, MS4A18.
- chr16:32,051,825–32,066,358, 3 genes (within-gene range 0–2): AC142381.1, IGHV1OR16-3, IGHV3OR16-9.
- chr21:7,744,962–9,129,752, 42 genes: SMIM11B, FAM243B, SMIM34B, KCNE1B, CU633980.1, FP671120.5, FP671120.4, MIR6724-1, FP671120.1, MIR3648-1, FP671120.2, FP671120.6, RNA5-8SN2, MIR6724-2, FP671120.3, FP671120.7, 5_8S_rRNA, FP236383.3, MIR6724-3, FP236383.1, FP236383.4, RNA5-8SN3, MIR6724-4, FP236383.2, FP236383.5, RNA5-8SN1, RPSAP68, CR381572.2, CR381572.1, LINC01666, CR381670.2, SNX18P10, MTCO1P1, CR381670.1, MIR3648-2, CR392039.1, CR392039.3, CDRT15P9, CR392039.4, TEKT4P2, SOWAHCP2, CR392039.2.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 233 genes in 12 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:2,530,064–2,565,382, 3 genes, copy number 6 (within-gene range 2–6): AL139246.5, TNFRSF14-AS1, TNFRSF14.
- chr2:87,249,095–87,253,750, 1 gene, copy number 5: LINC01955.
- chr9:64,369,394–64,413,142, 2 genes, copy number 16: ANKRD20A4P, RNU6-1193P.
- chr9:64,462,819–64,466,498, 2 genes, copy number 9: CR769776.2, CYP4F25P.
- chr9:68,228,651–68,229,312, 1 gene, copy number 14: AL353608.2.
- chr11:100,336,856–105,531,697, 83 genes, copy number 5 (broad region; genes not listed).
- chr15:32,182,551–32,186,475, 1 gene, copy number 10: AC068448.1.
- chr15:32,313,126–32,315,654, 1 gene, copy number 10: AC139426.1.
- chr15:32,436,503–32,455,634, 3 genes, copy number 13: DNM1P32, GOLGA8O, RN7SL539P.
- chr19:10,871,553–12,758,458, 128 genes, copy number 5–6 (broad region; genes not listed).
- chr19:22,974,883–23,003,176, 1 gene, copy number 5 (within-gene range 2–5): ZNF728.
- chr19:24,004,358–24,163,425, 7 genes, copy number 6: RNA5-8SP4, AC092279.1, ZNF254, AC092279.2, BNIP3P40, AC073534.2, AC073534.1.

Autosomal genes at a single copy (total copy number 1): 5,881. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
